Somatic mutation profile of tumor specimen TCGA-CJ-4882-01A (aliquot TCGA-CJ-4882-01A-02D-1429-08) from TCGA case TCGA-CJ-4882, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 57.7 years (21,074 days).
Specimen TCGA-CJ-4882-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 192eed6a-967b-41ec-aba0-8b32dfa79678.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4882-11A (Solid Tissue Normal), aliquot TCGA-CJ-4882-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d345d11-8142-4fab-a926-d9057aad7078

The open-access MAF lists 78 somatic variants for this specimen: 62 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 13, Nonsense Mutation 8, Frame Shift Del 7, 5'UTR 2, Frame Shift Ins 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AOX1 | c.2001+1G>A p.X667_splice | Splice Site (SNP) | VAF 12/210 reads (6%) | catalogued as COSV65981474; called by muse, mutect2
- APOB | c.2360C>T p.A787V | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51934554; called by muse, mutect2, varscan2
- ATG13 | c.1443A>G p.I481M (on ENST00000359513 / NM_001346321.1; = p.I444M on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.219); catalogued as COSV56319235; called by muse, mutect2, varscan2
- BAP1 | c.92A>C p.E31A | Missense Mutation (SNP) | VAF 59/378 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56234115, COSV56235544, COSV56236745, COSV56241651; called by muse, mutect2, varscan2
- BRIP1 | c.2020G>T p.D674Y | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51999177; called by muse, mutect2, varscan2
- CCDC25 | c.406A>C p.T136P | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV62958595, COSV62958702; called by muse, mutect2, varscan2
- DAND5 | c.201G>C p.Q67H | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV57684145; called by muse, mutect2, varscan2
- DCAF7 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV59003212; called by muse, mutect2, varscan2
- EP400 | c.3520C>T p.R1174* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as rs1372461877, COSV57771553; called by muse, mutect2, varscan2
- FOXK2 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.173); catalogued as COSV58878881; called by muse, mutect2, varscan2
- GEMIN7 | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV54319623; called by muse, mutect2, varscan2
- GPR180 | c.169A>G p.R57G | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV65385556; called by muse, mutect2, varscan2
- GRAMD1A | c.326A>G p.D109G | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV58766953; called by muse, mutect2
- HADH | c.292A>G p.S98G | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV58848079; called by muse, mutect2, varscan2
- HAT1 | c.341T>G p.I114S | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.072); catalogued as COSV51362481; called by muse, mutect2, varscan2
- HPS4 | c.1143A>C p.E381D | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1354437035, COSV61103369; called by muse, mutect2, varscan2
- IFIT2 | c.44A>C p.Q15P | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV51078854; called by muse, mutect2, varscan2
- KAT7 | c.1312G>C p.V438L | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52014360, COSV52015899; called by muse, mutect2
- LHFPL1 | c.371A>T p.Q124L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV64333367; called by muse, mutect2, varscan2
- LPA | c.2483A>T p.H828L | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV100307938; called by mutect2, varscan2
- LRP2 | c.1388A>G p.N463S | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.416); catalogued as rs202154723; called by muse, mutect2
- MYH6 | c.4688C>T p.A1563V | Missense Mutation (SNP) | VAF 21/303 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as COSV62450219; called by muse, mutect2
- NEMF | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.192); catalogued as COSV53591412; called by muse, mutect2
- NMT2 | c.1001T>A p.V334D | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.102); catalogued as COSV65382151; called by muse, mutect2, varscan2
- OR4A16 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.403); catalogued as rs143065334, COSV59043022; called by muse, mutect2, varscan2
- OR7G2 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59687871; called by muse, mutect2
- PDE4A | c.1870G>A p.G624S (on ENST00000380702 / NM_001111307.2; = p.G385S on NM_006202.3) | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV53355384; called by muse, mutect2
- PIGR | c.1318T>C p.W440R | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62903959; called by muse, mutect2, varscan2
- POMGNT1 | c.1094A>C p.N365T | Missense Mutation (SNP) | VAF 4/35 reads (11%) | PolyPhen probably damaging (0.914); catalogued as COSV64339882; called by muse, mutect2, varscan2
- PTPN4 | c.2233G>A p.G745S | Missense Mutation (SNP) | VAF 47/291 reads (16%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.859); catalogued as rs753221021, COSV55301223; called by muse, mutect2, varscan2
- RAB9B | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54587550, COSV99686004; called by muse, mutect2
- RBM23 | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 42/418 reads (10%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV57127695; called by muse, mutect2
- RFX6 | c.2231G>T p.C744F | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.52); catalogued as rs774495117, COSV100263641, COSV60584799; called by muse, mutect2, varscan2
- RYR3 | c.9139C>T p.R3047C (on ENST00000389232; = p.R3048C on NM_001036.6) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs763223227, COSV66787859; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SETD2 | c.6010del p.D2004Ifs*2 | Frame Shift Del (DEL) | VAF 34/284 reads (12%) | catalogued as COSV57437920; called by mutect2, pindel, varscan2
- SIAH2 | c.717C>G p.Y239* | Nonsense Mutation (SNP) | VAF 11/115 reads (10%) | catalogued as COSV57262163, COSV57262852; called by muse, mutect2, varscan2
- SLC19A3 | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.088); catalogued as COSV51452634; called by muse, mutect2, varscan2
- SLC22A6 | c.266C>A p.P89H | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as COSV64560208; called by muse, mutect2
- SLC35F3 | c.752T>A p.L251* (on ENST00000366617 / NM_001300845.1; = p.L320* on NM_173508.4) | Nonsense Mutation (SNP) | VAF 40/323 reads (12%) | catalogued as COSV64019543; called by muse, mutect2, varscan2
- ST8SIA6 | c.254A>T p.Q85L | Missense Mutation (SNP) | VAF 34/316 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV66461358; called by muse, mutect2, varscan2
- SUN2 | c.427T>C p.Y143H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV53303636; called by muse, mutect2, varscan2
- SYCP1 | c.2275G>T p.E759* | Nonsense Mutation (SNP) | VAF 24/190 reads (13%) | catalogued as COSV65697222; called by muse, mutect2, varscan2
- TAS2R50 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 23/177 reads (13%) | catalogued as COSV67855621; called by muse, mutect2, varscan2
- TMEM130 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 9/83 reads (11%) | catalogued as COSV59559104; called by muse, mutect2
- TMEM154 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV58590619; called by muse, mutect2
- UPF1 | c.2818T>C p.F940L (on ENST00000599848 / NM_001297549.2; = p.F929L on NM_002911.4) | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV53196180; called by muse, mutect2, varscan2
- WDR11 | c.2716G>T p.E906* | Nonsense Mutation (SNP) | VAF 14/96 reads (15%) | catalogued as COSV54788215; called by muse, mutect2, varscan2
- WNK4 | c.3378A>T p.E1126D | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV55904519; called by muse, mutect2, varscan2
- ZFPM2 | c.3361T>C p.C1121R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65873535; called by muse, mutect2, varscan2
- ZNF425 | c.463A>C p.N155H | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV65201258; called by muse, mutect2, varscan2
- ZNF518B | c.668A>G p.K223R | Missense Mutation (SNP) | VAF 54/495 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs958892090, COSV58722441; called by muse, mutect2, varscan2
- ZNF790 | c.1760del p.N587Ifs*66 | Frame Shift Del (DEL) | VAF 29/285 reads (10%) | catalogued as COSV63212431; called by mutect2, pindel, varscan2
- ZZEF1 | c.2620C>G p.R874G | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV67557360; called by muse, mutect2, varscan2
- CASP8AP2 | c.2844dup p.E949Rfs*4 | Frame Shift Ins (INS) | VAF 6/28 reads (21%) | called by mutect2, varscan2
- DSC3 | c.474del p.V159Lfs*15 | Frame Shift Del (DEL) | VAF 24/147 reads (16%) | called by mutect2, pindel, varscan2
- DST | c.21505del p.I7169Sfs*5 (on ENST00000361203 / NM_001374722.1; = p.I4866Sfs*5 on NM_015548.5) | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | called by mutect2, pindel, varscan2
- IGHG4 | c.604A>T p.K202* | Nonsense Mutation (SNP) | VAF 54/371 reads (15%) | called by muse, mutect2, varscan2
- OPRM1 | c.1090_1091del p.N364Lfs*9 | Frame Shift Del (DEL) | VAF 20/147 reads (14%) | called by mutect2, pindel, varscan2
- PCDH7 | c.2587G>T p.D863Y | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- PM20D2 | c.569del p.P190Hfs*17 | Frame Shift Del (DEL) | VAF 29/249 reads (12%) | called by mutect2, pindel, varscan2
- RTTN | c.2155_2156dup p.I720Sfs*22 | Frame Shift Ins (INS) | VAF 15/108 reads (14%) | called by mutect2, pindel, varscan2
- SMARCC2 | c.2091del p.E698Rfs*6 | Frame Shift Del (DEL) | VAF 9/96 reads (9%) | called by mutect2, pindel
- A4GNT | c.765A>G p.L255= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as COSV52628891; called by muse, mutect2, varscan2
- COL5A1 | c.327G>A p.K109= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as COSV65667716, COSV65668740; called by muse, mutect2
- DCAF8 | c.396T>C p.D132= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV58783659; called by muse, mutect2, varscan2
- DYRK3 | c.1734C>T p.P578= | Silent (SNP) | VAF 32/173 reads (18%) | catalogued as rs1213341935, COSV65606170; called by muse, mutect2, varscan2
- LRP4 | c.5670C>T p.D1890= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as COSV66135698; called by muse, mutect2
- MFSD2A | c.1509A>G p.K503= (on ENST00000372809 / NM_001136493.3; = p.K490= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 17/203 reads (8%) | catalogued as COSV65685555; called by muse, mutect2
- MYH13 | c.1806C>A p.P602= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs774277331, COSV52827977; called by muse, mutect2, varscan2
- OR2M4 | c.228C>A p.T76= | Silent (SNP) | VAF 8/210 reads (4%) | catalogued as COSV60708163; called by muse, mutect2
- OTUB1 | c.543C>A p.G181= | Silent (SNP) | VAF 23/179 reads (13%) | catalogued as COSV55360134; called by muse, mutect2, varscan2
- PGAP3 | c.948G>A p.K316= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs560138585, COSV54092964; called by muse, mutect2, varscan2
- SOCS3 | c.447G>A p.E149= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV58270336; called by muse, mutect2, varscan2
- TTN | c.81225A>T p.T27075= (on ENST00000591111; = p.T19651= on NM_003319.4) | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV60041028; called by muse, mutect2
- ZPBP | c.606T>A p.L202= | Silent (SNP) | VAF 32/197 reads (16%) | catalogued as COSV50425053; called by muse, mutect2, varscan2
- IL19 | c.-74C>G | 5'UTR (SNP) | VAF 15/107 reads (14%) | catalogued as COSV61592341, COSV61592933; called by muse, mutect2, varscan2
- LINC00518 | n.1028C>T | RNA (SNP) | VAF 35/332 reads (11%) | called by muse, mutect2, varscan2
- PAGE5 | c.-1G>C | 5'UTR (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99215839; called by muse, varscan2
